Somatic mutation profile of tumor specimen MMRF_1032_1_BM_CD138pos (aliquot MMRF_1032_1_BM_CD138pos_T2_TSE61_L00053) from MMRF case MMRF_1032, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.0 years (28,110 days).
Specimen MMRF_1032_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15d59f40-ec07-4e84-bd4b-00afe0b1dd07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1032_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1032_1_PB_Whole_C1_TSE61_L00073; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5ad1925-3fdc-45c1-86a5-0eedfa2f070e

The open-access MAF lists 117 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 35, Silent 18, 5'UTR 10, Nonsense Mutation 5, Intron 5, 3'Flank 2, 5'Flank 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 43/143 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAIAP2L1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50061024, COSV99133534; called by muse, mutect2, varscan2
- DCAKD | c.288del p.M96Ifs*15 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as COSV60202912; called by mutect2, pindel
- DOCK9 | c.3526G>A p.V1176I (on ENST00000376460 / NM_001366676.2; = p.V1177I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1471236386, COSV59643438; called by muse, mutect2, varscan2
- DYTN | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1179920970, COSV104438052; called by muse, mutect2, varscan2
- EBF2 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1243906122; called by muse, mutect2, varscan2
- FAT2 | c.12901C>T p.R4301C | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1445622376, COSV55818116; called by muse, mutect2, varscan2
- GPNMB | c.1240G>A p.V414M (on ENST00000381990 / NM_001005340.2; = p.V402M on NM_002510.3) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs146238405; called by muse, mutect2, varscan2
- GRID2 | c.2516C>A p.A839D | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99939674; called by muse, mutect2
- HPGD | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56661857; called by muse, mutect2, varscan2
- JAKMIP3 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as COSV53820916; called by muse, mutect2, varscan2
- KLHL40 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); catalogued as CM164350; called by muse, mutect2
- KRT38 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs571501521, COSV55845161; called by muse, mutect2, varscan2
- LY75 | c.2012G>A p.W671* | Nonsense Mutation (SNP) | VAF 65/130 reads (50%) | catalogued as rs779882968; called by muse, mutect2, varscan2
- NEFM | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1263864447, COSV55331428; called by muse, mutect2
- NR3C2 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV100678701; called by muse, mutect2, varscan2
- OR5AR1 | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1056426910, COSV57254264; called by muse, varscan2
- OR5AR1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.584); catalogued as COSV57254426; called by muse, mutect2, varscan2
- RFX4 | c.681C>A p.F227L (on ENST00000392842 / NM_213594.3; = p.F133L on NM_032491.6) | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.348); catalogued as COSV57581187, COSV99985327; called by muse, mutect2, varscan2
- SLIT2 | c.3235G>T p.D1079Y | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs756121317, COSV56572944; called by muse, mutect2, varscan2
- TAF1L | c.3728G>A p.R1243Q | Missense Mutation (SNP) | VAF 198/322 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs374466609; called by muse, mutect2, varscan2
- TNFRSF8 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs139117240; called by muse, mutect2, varscan2
- TYRO3 | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1282188739; called by muse, mutect2, varscan2
- ZNF451 | c.1430A>G p.N477S | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs758934788; called by muse, mutect2, varscan2
- ACTN4 | c.1253T>G p.F418C | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN1 | c.2297C>G p.P766R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CAPRIN2 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CCT8L2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DCAF12L2 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBN2 | c.2068G>C p.V690L | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- GATAD2B | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HOXA7 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); called by muse, mutect2
- HPGD | c.292A>T p.K98* | Nonsense Mutation (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- MPRIP | c.2109G>T p.Q703H | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NEK10 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- NELL1 | c.2411T>G p.F804C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, varscan2
- NKX6-1 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR6B2 | c.763T>G p.L255V | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PAPPA | c.3073T>C p.S1025P | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- PCDHA7 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 160/540 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP17 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SYCP2 | c.3460G>T p.G1154* | Nonsense Mutation (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- TRIM17 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- ZNF329 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- BMERB1 | c.462C>T p.I154= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- COL11A2 | c.3084C>T p.P1028= (on ENST00000341947 / NM_080680.3; = p.P921= on NM_080679.2) | Silent (SNP) | VAF 87/171 reads (51%) | catalogued as rs1370816589, COSV59493589; called by muse, mutect2, varscan2
- CPXM1 | c.1230C>T p.I410= | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as rs564339698, COSV101013683, COSV66045074; called by muse, mutect2, varscan2
- DIRAS1 | c.369C>T p.C123= | Silent (SNP) | VAF 53/440 reads (12%) | catalogued as rs1472666655, COSV60214932; called by muse, mutect2, varscan2
- GDPD3 | c.307C>T p.L103= | Silent (SNP) | VAF 70/143 reads (49%) | called by muse, mutect2, varscan2
- GJA8 | c.366C>T p.G122= | Silent (SNP) | VAF 89/177 reads (50%) | catalogued as rs782125496; called by muse, mutect2, varscan2
- KIFC3 | c.2226G>A p.V742= | Silent (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2, varscan2
- LRP2 | c.2748G>T p.P916= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV55555831; called by muse, mutect2, varscan2
- LZTR1 | c.2247C>T p.Y749= | Silent (SNP) | VAF 55/104 reads (53%) | catalogued as rs779077819, CM147047; ClinVar: likely benign; called by muse, mutect2, varscan2
- MTF1 | c.1980G>A p.E660= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- NPAP1 | c.2001C>T p.F667= | Silent (SNP) | VAF 32/326 reads (10%) | catalogued as COSV61504261, COSV61510081; called by muse, mutect2
- OR5AR1 | c.462G>T p.V154= | Silent (SNP) | VAF 44/91 reads (48%) | called by muse, varscan2
- PAH | c.1152C>G p.P384= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs281865458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXNA4 | c.2664C>T p.R888= | Silent (SNP) | VAF 127/267 reads (48%) | catalogued as rs777953678, COSV58138921; called by muse, mutect2, varscan2
- PNPLA7 | c.606G>C p.V202= | Silent (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.4218G>A p.R1406= | Silent (SNP) | VAF 34/196 reads (17%) | catalogued as COSV61201616; called by muse, mutect2, varscan2
- TJP3 | c.1143G>A p.T381= | Silent (SNP) | VAF 34/231 reads (15%) | catalogued as rs564498611, COSV53663506; called by muse, mutect2, varscan2
- ZNF688 | c.696C>A p.I232= | Silent (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- AC132812.1 | chr17:64749835 A>C | 5'Flank (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- ADCYAP1 | c.*58C>T | 3'UTR (SNP) | VAF 71/139 reads (51%) | called by muse, mutect2, varscan2
- AFAP1 | c.1810+113T>C | Intron (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- AGTR1 | c.-47-1076C>A | Intron (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- AKAIN1 | c.*1461A>G | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*499C>T | 3'UTR (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- BCL6 | chr3:187745513 T>C | 5'Flank (SNP) | VAF 44/86 reads (51%) | called by muse, varscan2
- CAPN15 | c.*160C>T | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.-571G>C | 5'UTR (SNP) | VAF 85/184 reads (46%) | called by muse, mutect2, varscan2
- CCER1 | c.*232T>C | 3'UTR (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- CELSR1 | c.*2231T>G | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- CELSR1 | c.*2146T>C | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, varscan2
- CGB5 | c.-146T>C | 5'UTR (SNP) | VAF 64/558 reads (11%) | called by muse, varscan2
- CGNL1 | c.*1729del | 3'UTR (DEL) | VAF 157/506 reads (31%) | called by mutect2, pindel, varscan2
- COL6A4P2 | n.1295C>T | RNA (SNP) | VAF 23/92 reads (25%) | catalogued as rs182860387; called by muse, mutect2, varscan2
- CTBP2 | c.-13A>T | 5'UTR (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- DNAJB7 | c.*1320A>T | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- ECPAS | c.*559A>G | 3'UTR (SNP) | VAF 8/137 reads (6%) | catalogued as rs1564489313; called by muse, mutect2
- ERC2 | c.-20C>T | 5'UTR (SNP) | VAF 33/84 reads (39%) | catalogued as rs1219614934; called by muse, mutect2, varscan2
- FAM13B | c.*892A>G | 3'UTR (SNP) | VAF 26/145 reads (18%) | catalogued as rs115109738; called by muse, mutect2, varscan2
- FAM153CP | n.703+279G>A | Intron (SNP) | VAF 54/264 reads (20%) | called by muse, mutect2, varscan2
- GABRB3 | c.*328G>T | 3'UTR (SNP) | VAF 53/191 reads (28%) | called by muse, mutect2, varscan2
- GNB4 | c.*3499C>T | 3'UTR (SNP) | VAF 45/98 reads (46%) | catalogued as rs1242531324; called by muse, mutect2, varscan2
- GNG4 | chr1:235548863 G>A | 3'Flank (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- GPR26 | c.*4230G>T | 3'UTR (SNP) | VAF 12/134 reads (9%) | catalogued as rs1482435175; called by muse, mutect2
- HOXB3 | c.*311C>T | 3'UTR (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- HTR2A | c.-501G>T | 5'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- IGF2BP1 | c.*6554G>A | 3'UTR (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- KALRN | c.*203T>G | 3'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- KCNIP1 | chr5:170736497 G>T | 3'Flank (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- KCNIP4 | c.61+100571A>G | Intron (SNP) | VAF 70/200 reads (35%) | called by muse, mutect2, varscan2
- KIAA0930 | c.*3356G>T | 3'UTR (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2
- KNDC1 | c.*574C>A | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2
- LARP4 | c.*860del | 3'UTR (DEL) | VAF 13/59 reads (22%) | called by mutect2, varscan2
- LNP1 | c.-27G>T | 5'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as COSV67346248; called by muse, mutect2
- LRRC15 | c.*1454G>A | 3'UTR (SNP) | VAF 47/95 reads (49%) | catalogued as rs1168618208; called by muse, mutect2, varscan2
- MAT1A | c.*389C>A | 3'UTR (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2
- NAA35 | c.-122T>A | 5'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- NUAK2 | c.*535T>A | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- RBMX | c.-108C>T | 5'UTR (SNP) | VAF 84/91 reads (92%) | catalogued as rs1355099280, COSV57810061; called by muse, mutect2, varscan2
- RGMA | c.*1240G>A | 3'UTR (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- RNASE9 | c.*228G>A | 3'UTR (SNP) | VAF 49/112 reads (44%) | catalogued as rs139916800; called by muse, mutect2, varscan2
- RUFY2 | c.1311-739G>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- SC5D | c.*5397A>G | 3'UTR (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- SCN4B | c.*3514G>A | 3'UTR (SNP) | VAF 18/184 reads (10%) | catalogued as rs1219998899; called by muse, mutect2
- SLC25A21 | c.-209G>A | 5'UTR (SNP) | VAF 67/137 reads (49%) | catalogued as rs575057984; called by muse, mutect2, varscan2
- SLC44A1 | c.*1976A>G | 3'UTR (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- SLC5A1 | c.*1712G>A | 3'UTR (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- SPCS3 | c.*256del | 3'UTR (DEL) | VAF 26/196 reads (13%) | catalogued as rs968497509; called by mutect2, pindel*, varscan2*
- TEX26 | c.-13C>T | 5'UTR (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*173_*176del | 3'UTR (DEL) | VAF 18/43 reads (42%) | catalogued as rs1327406897; called by mutect2, pindel, varscan2
- WNT2 | c.*925C>G | 3'UTR (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- WNT2 | c.*119C>T | 3'UTR (SNP) | VAF 122/278 reads (44%) | called by muse, varscan2
- ZFAND5 | c.*2523G>C | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- ZNF781 | c.*493C>T | 3'UTR (SNP) | VAF 19/248 reads (8%) | called by muse, mutect2
